Somatic mutation profile of tumor specimen TARGET-10-PARTWH-09A (aliquot TARGET-10-PARTWH-09A-01D) from TARGET case TARGET-10-PARTWH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.7 years (4,270 days).
Specimen TARGET-10-PARTWH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b59cc470-9c20-4f1b-a154-4fa681ebd2c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTWH-10A (Blood Derived Normal), aliquot TARGET-10-PARTWH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/546b2c9c-a04c-43d2-992e-44a5c831ec0b

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.3992G>A p.R1331Q (on ENST00000370717 / NM_001366005.1; = p.R1275Q on NM_012302.4) | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs748651558; called by muse, mutect2, varscan2
- GRIK2 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs770114112, COSV59720677; called by muse, mutect2, varscan2
- NIPAL4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs374137299; called by muse, mutect2, varscan2
- OPN5 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as rs1172262178; called by muse, mutect2, varscan2
- RTL1 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1405383807, COSV66017174; called by muse, mutect2, varscan2
- WDR90 | c.1437G>A p.T479= | Splice Region (SNP) | VAF 39/84 reads (46%) | catalogued as rs757489630; called by muse, mutect2, varscan2
- DPP6 | c.633T>G p.Y211* (on ENST00000377770 / NM_001364500.2; = p.Y149* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2
- GTF2I | c.155_156insGACCCTC p.D53Tfs*10 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- KRBA1 | c.1254T>G p.S418= | Silent (SNP) | VAF 71/139 reads (51%) | called by muse, mutect2, varscan2
- FBXL18 | c.*22G>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | catalogued as rs748340151; called by muse, mutect2, varscan2
- PKM | c.*140C>G | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
